Somatic mutation profile of tumor specimen TCGA-CC-5262-01A (aliquot TCGA-CC-5262-01A-01D-A12Z-10) from TCGA case TCGA-CC-5262, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIC; Tumor grade: G1; Age at diagnosis: 67.9 years (24,787 days).
Specimen TCGA-CC-5262-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3180651f-9c2c-493b-a13e-505c6f149718.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-5262-10B (Blood Derived Normal), aliquot TCGA-CC-5262-10B-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66b3d38c-8601-4f23-80c4-6548019f7c44

The open-access MAF lists 139 somatic variants for this specimen: 106 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 30, Nonsense Mutation 7, Splice Site 4, Frame Shift Ins 2, Frame Shift Del 2, Intron 1, RNA 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.3424C>T p.Q1142* | Nonsense Mutation (SNP) | VAF 41/226 reads (18%) | hotspot (GDC flag); catalogued as COSV61371666; called by muse, mutect2, varscan2
- CTNNB1 | c.1149G>C p.W383C | Missense Mutation (SNP) | VAF 53/250 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV62692553, COSV62700446, COSV62722790; called by muse, mutect2, varscan2
- STUB1 | c.719T>C p.M240T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs587777345, CM144454, COSV50202299; ClinVar: pathogenic; called by muse, mutect2
- ABCE1 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV56848615; called by muse, mutect2, varscan2
- ACO1 | c.499A>G p.M167V | Missense Mutation (SNP) | VAF 60/364 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV59383566; called by muse, mutect2, varscan2
- ADAM10 | c.1820G>T p.C607F | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53054012; called by muse, mutect2, varscan2
- ADAMTS14 | c.807C>G p.D269E | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV64605431; called by muse, mutect2, varscan2
- ADAMTS9 | c.3280G>C p.E1094Q | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV55782874, COSV55788452; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1269C>A p.Y423* | Nonsense Mutation (SNP) | VAF 9/119 reads (8%) | catalogued as COSV58444545, COSV58444814; called by muse, mutect2
- APCDD1L | c.1366C>A p.H456N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV64487668; called by muse, mutect2, varscan2
- ATP1B4 | c.525G>T p.W175C (on ENST00000218008 / NM_001142447.3; = p.W171C on NM_012069.5) | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54314434; called by muse, mutect2, varscan2
- BCL11A | c.1564C>A p.Q522K (on ENST00000335712 / NM_001365609.1; = p.Q556K on NM_018014.4) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV59635489; called by muse, mutect2, varscan2
- BPNT2 | c.917C>G p.A306G | Missense Mutation (SNP) | VAF 63/301 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52906583; called by muse, mutect2, varscan2
- BRINP2 | c.1917T>A p.F639L | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV64179579; called by muse, mutect2, varscan2
- CCNJL | c.481A>G p.R161G | Missense Mutation (SNP) | VAF 91/462 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99979628; called by muse, mutect2, varscan2
- CD22 | c.166T>C p.F56L | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1161076737, COSV50062988; called by muse, mutect2, varscan2
- COL12A1 | c.4702A>T p.R1568* | Nonsense Mutation (SNP) | VAF 30/200 reads (15%) | catalogued as COSV59405005; called by muse, mutect2, varscan2
- CSMD2 | c.9319C>A p.R3107S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.16); catalogued as COSV53949500; called by muse, mutect2, varscan2
- CSPG4 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs775706392, COSV57900050; called by muse, mutect2, varscan2
- DENND4C | c.1954-2A>G p.X652_splice | Splice Site (SNP) | VAF 69/378 reads (18%) | catalogued as COSV66823123; called by muse, mutect2, varscan2
- DLX6 | c.649A>T p.N217Y | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50297081; called by muse, mutect2, varscan2
- DNAH3 | c.5809G>A p.E1937K | Missense Mutation (SNP) | VAF 87/408 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0.202); catalogued as COSV54530540; called by muse, mutect2, varscan2
- EI24 | c.537G>T p.L179F | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54020729; called by muse, mutect2
- ELMOD1 | c.506del p.P169Lfs*47 | Frame Shift Del (DEL) | VAF 38/169 reads (22%) | catalogued as COSV56196951; called by mutect2, pindel, varscan2
- EPG5 | c.1030A>G p.K344E | Missense Mutation (SNP) | VAF 65/398 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56354681; called by muse, mutect2, varscan2
- EPM2A | c.443A>C p.N148T | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV62297468; called by muse, mutect2, varscan2
- EVX2 | c.323C>A p.A108E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.158); catalogued as COSV57964759; called by mutect2, varscan2
- FAM83H | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554624202, COSV66354130; called by muse, mutect2, varscan2
- GAD1 | c.148T>G p.F50V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.066); catalogued as COSV60153826; called by muse, mutect2
- GNL2 | c.1580C>A p.T527K | Missense Mutation (SNP) | VAF 14/363 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV56171192; called by muse, mutect2
- HAS2 | c.751T>A p.W251R | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58266539; called by muse, mutect2, varscan2
- HSPG2 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV101021322, COSV65975863; called by muse, mutect2, varscan2
- IDH1 | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as COSV100576054, COSV100577057; called by muse, mutect2, varscan2
- IGF1R | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV51351455; called by muse, mutect2, varscan2
- IGF1R | c.1913A>G p.N638S | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144533252; called by muse, mutect2, varscan2
- INPP5F | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs753033639, COSV62823204; called by muse, mutect2, varscan2
- IQUB | c.2254T>A p.F752I | Missense Mutation (SNP) | VAF 70/333 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772051410, COSV61241831; called by muse, mutect2, varscan2
- IRF4 | c.214A>T p.K72* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV66706066; called by muse, mutect2
- KIF18A | c.409A>C p.M137L | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV54186688; called by muse, mutect2, varscan2
- KLHL40 | c.445G>C p.A149P | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55134914, COSV99825633; called by muse, mutect2, varscan2
- LRG1 | c.932A>G p.Y311C | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1272629422, COSV56705559; called by muse, mutect2, varscan2
- LRRC28 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as rs539126226, COSV57341030; called by muse, mutect2, varscan2
- LTBP1 | c.557G>C p.C186S | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63195665; called by muse, mutect2, varscan2
- MAP4 | c.1595A>C p.K532T | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV64243758; called by muse, mutect2, varscan2
- MB21D2 | c.755T>A p.L252H | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66665471; called by muse, mutect2, varscan2
- MBD5 | c.3624C>A p.N1208K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as COSV68698658; called by muse, mutect2, varscan2
- MED14 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 132/328 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61358197; called by muse, mutect2, varscan2
- MRC2 | c.1117+1G>T p.X373_splice | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as COSV57643340; called by muse, mutect2, varscan2
- MUC16 | c.37315G>T p.G12439C | Missense Mutation (SNP) | VAF 65/299 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV67485884; called by muse, mutect2, varscan2
- NCOA2 | c.1705A>G p.M569V | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1411121418, COSV71764677; called by muse, mutect2, varscan2
- NLRP1 | c.3440T>C p.V1147A | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.429); catalogued as COSV52575488; called by muse, mutect2
- NOTCH3 | c.1829C>A p.S610Y | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV54645446; called by muse, mutect2, varscan2
- OBSCN | c.6814T>C p.F2272L | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.965); catalogued as COSV52814586; called by muse, mutect2, varscan2
- OGA | c.2285T>A p.L762H | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV63382970; called by muse, mutect2, varscan2
- OR10Z1 | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 80/483 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63524037, COSV63526097; called by muse, mutect2, varscan2
- OR2L13 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV63559039; called by muse, mutect2, varscan2
- OR4N5 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 90/376 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs139546094; called by muse, mutect2, varscan2
- OR6Y1 | c.777G>T p.M259I | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56931090; called by muse, mutect2, varscan2
- PAN3 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs775770672, COSV66707094; called by muse, mutect2, varscan2
- PHACTR1 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100277760; called by muse, varscan2
- PHC3 | c.2492A>T p.N831I (on ENST00000494943 / NM_001308116.2; = p.N843I on NM_024947.4) | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV71949213; called by muse, mutect2, varscan2
- PKHD1L1 | c.2546C>A p.P849H | Missense Mutation (SNP) | VAF 106/320 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV65750359, COSV65753016; called by muse, mutect2, varscan2
- PLEKHF2 | c.573T>G p.F191L | Missense Mutation (SNP) | VAF 87/538 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV59542277; called by muse, mutect2, varscan2
- POLR2F | c.450C>A p.S150= | Splice Region (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100329795; called by muse, mutect2, varscan2
- PPIP5K2 | c.1700A>T p.E567V | Missense Mutation (SNP) | VAF 102/504 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58608733; called by muse, mutect2, varscan2
- PRDM2 | c.416G>T p.W139L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.692); catalogued as COSV52453633; called by muse, mutect2, varscan2
- PRF1 | c.701C>A p.S234* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as COSV64615702; called by muse, mutect2, varscan2
- PRICKLE1 | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61545947; called by muse, mutect2, varscan2
- PTCHD4 | c.2228C>A p.T743N | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as rs755804869, COSV59794309; called by muse, mutect2, varscan2
- PXDNL | c.1217C>A p.T406N | Missense Mutation (SNP) | VAF 95/318 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV62496234; called by muse, mutect2, varscan2
- RANBP17 | c.160G>C p.G54R | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.248); catalogued as COSV66655510; called by muse, mutect2, varscan2
- RAPH1 | c.377A>G p.H126R | Missense Mutation (SNP) | VAF 34/562 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.024); catalogued as COSV57356513; called by muse, mutect2
- RHAG | c.137T>C p.I46T | Missense Mutation (SNP) | VAF 72/314 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV57705897; called by mutect2, varscan2
- RPTOR | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100157465, COSV60810057; called by muse, mutect2, varscan2
- RSAD1 | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51956893; called by muse, mutect2, varscan2
- RTP1 | c.97A>T p.T33S | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as COSV56619300; called by muse, mutect2, varscan2
- SCN4A | c.4648C>A p.P1550T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV71128578; called by muse, mutect2, varscan2
- SERTAD4 | c.511C>G p.P171A | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV65399942; called by muse, mutect2
- SFI1 | c.1316C>A p.P439H (on ENST00000400288 / NM_001007467.3; = p.P408H on NM_014775.4) | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101192122, COSV66292484; called by muse, mutect2, varscan2
- SH3D19 | c.1568A>T p.Y523F | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.229); catalogued as COSV58793113; called by muse, mutect2, varscan2
- SH3GLB1 | c.478-2A>G p.X160_splice | Splice Site (SNP) | VAF 87/422 reads (21%) | catalogued as COSV65280733; called by muse, mutect2, varscan2
- SLC13A3 | c.1431C>A p.F477L | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV51721523; called by muse, mutect2
- SLC25A12 | c.36T>A p.D12E | Missense Mutation (SNP) | VAF 50/306 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV55536333; called by muse, mutect2, varscan2
- SLC4A3 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV56092803, COSV99813002; called by muse, mutect2, varscan2
- SLC4A7 | c.835T>G p.S279A | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV55401579; called by muse, mutect2, varscan2
- SLC9C2 | c.54C>A p.C18* | Nonsense Mutation (SNP) | VAF 58/390 reads (15%) | catalogued as COSV62948486; called by muse, mutect2, varscan2
- SLC9C2 | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 61/394 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV62948493; called by muse, mutect2, varscan2
- SLITRK3 | c.2206G>A p.V736M | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as rs989521402, COSV99579585; called by muse, mutect2, varscan2
- SPATA16 | c.65T>G p.V22G | Missense Mutation (SNP) | VAF 157/736 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV63532236; called by muse, mutect2, varscan2
- STRADA | c.391G>T p.V131L (on ENST00000336174 / NM_001363786.1; = p.V94L on NM_153335.6) | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55564089; called by muse, mutect2, varscan2
- SYT10 | c.93G>A p.W31* | Nonsense Mutation (SNP) | VAF 14/137 reads (10%) | catalogued as COSV57344266; called by muse, mutect2
- TAS1R2 | c.2438A>G p.Y813C | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64746712; called by muse, mutect2, varscan2
- TBX18 | c.1277C>A p.T426N | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV63737022; called by muse, mutect2, varscan2
- TEKT3 | c.1253T>A p.L418Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.752); catalogued as rs747437138, COSV58629262; called by muse, mutect2, varscan2
- TNFRSF10D | c.769G>T p.V257F | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV100441690, COSV57036991; called by muse, mutect2, varscan2
- TRPM8 | c.2114T>A p.V705E | Missense Mutation (SNP) | VAF 104/601 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV61223641; called by muse, mutect2, varscan2
- VCAN | c.2612A>G p.E871G | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV54114046; called by muse, mutect2
- WASHC4 | c.2143C>A p.P715T | Missense Mutation (SNP) | VAF 68/385 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV59891646; called by muse, mutect2, varscan2
- ZNF331 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV53479203; called by muse, mutect2, varscan2
- CPS1 | c.984dup p.Q329Tfs*34 | Frame Shift Ins (INS) | VAF 40/237 reads (17%) | called by mutect2, pindel, varscan2
- IGKV2-28 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 31/411 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- POLR2A | c.2188G>T p.G730W | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB6D | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 92/1488 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- RWDD2A | c.76_79del p.Q26Efs*3 | Frame Shift Del (DEL) | VAF 18/125 reads (14%) | called by mutect2, pindel
- STAT2 | c.1433_1440+8del p.X478_splice | Splice Site (DEL) | VAF 16/100 reads (16%) | called by mutect2, pindel, varscan2
- TESK2 | c.1528_1529dup p.E511Mfs*35 | Frame Shift Ins (INS) | VAF 17/128 reads (13%) | called by mutect2, pindel, varscan2
- A2ML1 | c.4305C>T p.V1435= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV55296760; called by muse, mutect2, varscan2
- AC006059.2 | c.843G>T p.S281= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs749301195, COSV59606074, COSV59608925; called by muse, mutect2, varscan2
- CCDC93 | c.900A>C p.L300= | Silent (SNP) | VAF 69/335 reads (21%) | catalogued as COSV60123561; called by muse, mutect2, varscan2
- EVC2 | c.3082C>T p.L1028= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV60400512; called by muse, mutect2, varscan2
- FBXL19 | c.717G>A p.K239= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as rs747165398, COSV57944963; called by muse, varscan2
- GPM6A | c.720C>T p.A240= | Silent (SNP) | VAF 38/199 reads (19%) | catalogued as COSV54557035; called by muse, mutect2, varscan2
- GPR149 | c.1860G>A p.E620= | Silent (SNP) | VAF 47/488 reads (10%) | catalogued as COSV67669309; called by muse, mutect2, varscan2
- HTR5A | c.360C>T p.C120= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs757620241, COSV55285389; called by muse, mutect2, varscan2
- JADE3 | c.6A>G p.K2= | Silent (SNP) | VAF 62/195 reads (32%) | catalogued as COSV54469320; called by muse, mutect2, varscan2
- LCE1C | c.198A>T p.G66= | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as rs565723067, COSV64218261; called by muse, mutect2, varscan2
- LILRB4 | c.279A>T p.A93= | Silent (SNP) | VAF 92/497 reads (19%) | catalogued as COSV54406731; called by muse, mutect2, varscan2
- METTL2B | c.303T>G p.P101= | Silent (SNP) | VAF 105/601 reads (17%) | catalogued as COSV52310354; called by muse, varscan2
- MROH5 | c.3672C>T p.C1224= | Silent (SNP) | VAF 34/215 reads (16%) | catalogued as COSV61472124, COSV61472588; called by muse, mutect2, varscan2
- NAGLU | c.2082G>A p.Q694= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV56795948; called by muse, mutect2, varscan2
- POLR2A | c.2187A>G p.P729= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as rs140982359; called by muse, mutect2
- PON1 | c.78A>C p.T26= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as COSV55933635; called by muse, mutect2, varscan2
- PROM2 | c.2151C>T p.A717= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV58300162; called by muse, mutect2, varscan2
- PTPRF | c.2835C>T p.N945= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs368237069; called by muse, mutect2, varscan2
- PXDN | c.1773C>A p.R591= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV53243977; called by muse, mutect2, varscan2
- RPS4Y2 | c.681C>T p.V227= | Silent (SNP) | VAF 123/295 reads (42%) | catalogued as COSV56488848; called by muse, mutect2, varscan2
- SLITRK3 | c.2205C>A p.P735= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs372406969; called by muse, mutect2, varscan2
- SMYD2 | c.663G>T p.L221= | Silent (SNP) | VAF 61/173 reads (35%) | catalogued as COSV65291596; called by muse, mutect2, varscan2
- STC1 | c.33G>A p.L11= | Silent (SNP) | VAF 60/247 reads (24%) | catalogued as rs868282289, COSV51689681; called by muse, mutect2, varscan2
- TACC2 | c.1026G>T p.P342= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs201912981, COSV57768556; called by muse, mutect2, varscan2
- TBX18 | c.1278C>T p.T426= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as rs771176205, COSV63736150; called by muse, mutect2, varscan2
- TRMT44 | c.1851G>A p.A617= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as rs1466820839, COSV67664726; called by muse, mutect2
- WBP11 | c.1047A>G p.V349= | Silent (SNP) | VAF 61/346 reads (18%) | catalogued as COSV53764360; called by muse, mutect2, varscan2
- WDFY3 | c.3954A>G p.P1318= | Silent (SNP) | VAF 40/224 reads (18%) | catalogued as COSV55711327; called by muse, mutect2, varscan2
- ZNF221 | c.1833A>C p.L611= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV52109389, COSV52110801; called by muse, mutect2, varscan2
- ZNF318 | c.4959A>T p.L1653= | Silent (SNP) | VAF 56/278 reads (20%) | catalogued as COSV58936384; called by muse, varscan2
- F13A1 | c.1113-9259C>A | Intron (SNP) | VAF 34/185 reads (18%) | called by muse, mutect2, varscan2
- GUCY2C | c.*2C>A | 3'UTR (SNP) | VAF 84/540 reads (16%) | catalogued as COSV99663851; called by muse, mutect2, varscan2
- PARGP1 | n.1897G>T | RNA (SNP) | VAF 197/1093 reads (18%) | called by muse, mutect2, varscan2
